Gene-level copy-number profile of tumor specimen HCM-CSHL-0246-C19-86A from HCMI case HCM-CSHL-0246-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: GX; Age at diagnosis: 55.9 years (20,434 days).
Specimen HCM-CSHL-0246-C19-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 344b90dc-4c4b-40e1-bf62-e7319bea23dc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0246-C19-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/899f8c96-5ff3-4bf6-908a-5f484ff17719

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 324; copy number 1: 2,068; copy number 2: 38,642; copy number 3: 14,313; copy number 4: 3,097; copy number 5: 236; copy number 6: 126; copy number 7: 105.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 467 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:38,601,418–38,617,344, 2 genes, copy number 6: ABCD1P2, AL133173.2.
- chr12:37,575,587–48,982,620, 223 genes, copy number 5 (broad region; genes not listed).
- chr15:21,980,277–22,126,434, 10 genes, copy number 6: OR11J6P, AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P, OR4H6P, OR4M2, OR4N4, OR4N3P.
- chr18:45,034–11,618,315, 232 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,068. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
